Somatic mutation profile of cancer-model specimen HCM-BROD-0408-C71-85R (3D Neurosphere, passage 9; aliquot HCM-BROD-0408-C71-85R-01D-A80U-36), derived from the recurrence tumor of HCMI case HCM-BROD-0408-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.3 years (25,328 days).
Specimen HCM-BROD-0408-C71-85R: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 150161c8-3dd3-4351-834b-27981c96c111.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0408-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0408-C71-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2451b9e-a5d8-457a-a2e9-372ca1089684

The open-access MAF lists 175 somatic variants for this specimen: 130 protein-altering or splice-affecting, 38 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 38, Nonsense Mutation 13, Frame Shift Del 8, Intron 4, Splice Site 3, Splice Region 3, Frame Shift Ins 3, In Frame Del 2, RNA 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SOS1 | c.806T>G p.M269R | Missense Mutation (SNP) | VAF 150/339 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs137852813, CM070275, CM074570, COSV67674247, COSV67676625; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TREM2 | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 194/384 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs201258663, CM130449, COSV58294024; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.5003G>A p.R1668H | Missense Mutation (SNP) | VAF 205/609 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs566240276, COSV70028171; called by muse, mutect2, varscan2
- ABHD12B | c.1057G>A p.V353M (on ENST00000337334 / NM_001206673.2; = p.V276M on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 106/218 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs142210572, COSV53585701; called by muse, mutect2, varscan2
- BOD1L1 | c.3016G>A p.D1006N | Missense Mutation (SNP) | VAF 185/247 reads (75%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs778855949; called by muse, mutect2, varscan2
- CCDC181 | c.778T>G p.S260A | Missense Mutation (SNP) | VAF 215/454 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV63155981; called by muse, mutect2
- CELSR2 | c.8527T>C p.C2843R | Missense Mutation (SNP) | VAF 90/315 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.045); catalogued as rs1388043247, COSV54780105; called by muse, mutect2, varscan2
- CSTF2 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 205/509 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.122); catalogued as rs776956075, COSV100802907; called by muse, mutect2, varscan2
- DLST | c.923A>T p.E308V | Missense Mutation (SNP) | VAF 113/253 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs749277580; called by muse, mutect2, varscan2
- ESRP1 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 113/252 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as rs201842226; called by muse, mutect2, varscan2
- EYA1 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 126/285 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs765493132, COSV58160092; called by muse, mutect2, varscan2
- FLG | c.10246G>A p.E3416K | Missense Mutation (SNP) | VAF 290/628 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as rs140368354; called by muse, mutect2, varscan2
- FLRT1 | c.616G>C p.D206H | Missense Mutation (SNP) | VAF 26/521 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104370709; called by muse, mutect2
- GCDH | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 42/286 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.942); catalogued as rs761135089; called by muse, varscan2
- GPR101 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 345/682 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1040736572, COSV104402171, COSV99981639; called by muse, mutect2, varscan2
- IL2RB | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 121/257 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs865902855, COSV53427807; called by muse, mutect2, varscan2
- KRT19 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 256/519 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs774483519; called by muse, mutect2, varscan2
- LOXHD1 | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 107/110 reads (97%) | SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs748673610; called by muse, mutect2, varscan2
- LRIG3 | c.320A>G p.N107S | Missense Mutation (SNP) | VAF 136/286 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs151174055; called by muse, mutect2, varscan2
- MICAL1 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 215/414 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1256879195; called by muse, mutect2, varscan2
- MMEL1 | c.2137C>T p.Q713* | Nonsense Mutation (SNP) | VAF 111/547 reads (20%) | catalogued as rs771512368; called by muse, mutect2, varscan2
- MTBP | c.2042G>A p.R681H | Missense Mutation (SNP) | VAF 171/336 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs143250160; called by muse, mutect2, varscan2
- MYH14 | c.3875G>A p.R1292Q | Missense Mutation (SNP) | VAF 28/311 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as rs372963420, COSV51813479; called by muse, mutect2
- MYT1 | c.1727A>G p.E576G | Missense Mutation (SNP) | VAF 318/628 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60513754; called by muse, varscan2
- NLRP11 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 43/141 reads (30%) | catalogued as rs751156777, COSV64085872; called by muse, mutect2, varscan2
- NOBOX | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 137/454 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99779608; called by muse, mutect2, varscan2
- NPAS3 | c.820C>T p.R274C (on ENST00000356141 / NM_001164749.2; = p.R242C on NM_022123.3) | Missense Mutation (SNP) | VAF 155/296 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100640859; called by muse, mutect2, varscan2
- NR0B2 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 189/411 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs199619628; called by muse, mutect2, varscan2
- NUP62CL | c.70A>G p.T24A | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.991); catalogued as rs368654503; called by muse, mutect2
- PDILT | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 159/350 reads (45%) | catalogued as rs139247719, COSV56700444; called by muse, mutect2, varscan2
- PIEZO1 | c.5295C>G p.N1765K | Missense Mutation (SNP) | VAF 53/406 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.301); catalogued as rs191843423; called by muse, mutect2, varscan2
- PIK3CD | c.1299G>C p.K433N | Missense Mutation (SNP) | VAF 25/453 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1378083934; called by muse, mutect2
- PINX1 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 169/370 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.904); catalogued as rs371353496; called by muse, mutect2, varscan2
- PLCZ1 | c.1310C>G p.T437S | Missense Mutation (SNP) | VAF 124/274 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); catalogued as rs367728469; called by muse, mutect2, varscan2
- RADX | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 222/466 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as COSV65318474; called by muse, mutect2, varscan2
- RYR3 | c.3389G>A p.R1130H | Missense Mutation (SNP) | VAF 108/246 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as rs558475472, COSV101212797; called by muse, mutect2, varscan2
- SENP7 | c.2573+1G>A p.X858_splice | Splice Site (SNP) | VAF 21/164 reads (13%) | catalogued as rs1477839754, COSV58612718; called by muse, mutect2, varscan2
- TMTC4 | c.427C>T p.H143Y (on ENST00000376234 / NM_001350577.2; = p.H162Y on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/481 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1187004586, COSV60893320; called by muse, mutect2
- TOPBP1 | c.2795C>T p.A932V | Missense Mutation (SNP) | VAF 105/229 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1479160754, COSV53443029; called by muse, mutect2, varscan2
- UGT2B15 | c.794T>C p.F265S | Missense Mutation (SNP) | VAF 167/256 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs1407552690; called by muse, varscan2
- UNC45B | c.2245C>T p.R749W | Missense Mutation (SNP) | VAF 97/264 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.613); catalogued as rs746256786; called by muse, mutect2, varscan2
- USPL1 | c.2149C>T p.R717C | Missense Mutation (SNP) | VAF 174/174 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs577697601, COSV99687256; called by muse, mutect2, varscan2
- WDFY3 | c.1702C>T p.R568* | Nonsense Mutation (SNP) | VAF 109/141 reads (77%) | catalogued as COSV55707720; called by muse, mutect2, varscan2
- WDFY4 | c.8869G>T p.V2957L | Missense Mutation (SNP) | VAF 50/266 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.575); catalogued as COSV55423883; called by muse, mutect2, varscan2
- ZAN | c.3532T>C p.C1178R | Missense Mutation (SNP) | VAF 38/600 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771833490; called by muse, mutect2
- ZNF831 | c.1038C>G p.Y346* | Nonsense Mutation (SNP) | VAF 38/633 reads (6%) | catalogued as COSV99057613; called by muse, mutect2
- ABI3BP | c.200T>C p.V67A | Missense Mutation (SNP) | VAF 170/375 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AC138647.1 | c.173A>G p.Y58C | Missense Mutation (SNP) | VAF 204/675 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ADPRHL1 | c.2857G>A p.A953T | Missense Mutation (SNP) | VAF 230/497 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AMOT | c.2201T>C p.I734T (on ENST00000371959 / NM_001113490.1; = p.I325T on NM_133265.3) | Missense Mutation (SNP) | VAF 172/370 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- AQR | c.2404T>C p.F802L | Missense Mutation (SNP) | VAF 114/222 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ATG2A | c.2109T>C p.G703= | Splice Region (SNP) | VAF 144/294 reads (49%) | called by muse, mutect2, varscan2
- BEST4 | c.1030C>G p.L344V | Missense Mutation (SNP) | VAF 48/470 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- BNC2 | c.1732A>G p.T578A | Missense Mutation (SNP) | VAF 128/387 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTBD17 | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 100/807 reads (12%) | called by muse, mutect2, varscan2
- CACNA2D2 | c.2146A>G p.T716A (on ENST00000479441 / NM_001174051.3; = p.T709A on NM_006030.4) | Missense Mutation (SNP) | VAF 138/312 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.164); called by muse, varscan2
- CCDC177 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 289/532 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CHRNB1 | c.1257dup p.I420Yfs*96 | Frame Shift Ins (INS) | VAF 157/405 reads (39%) | called by mutect2, pindel, varscan2
- COL1A1 | c.3707A>G p.K1236R | Missense Mutation (SNP) | VAF 284/535 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DGKK | c.2248C>A p.P750T | Missense Mutation (SNP) | VAF 252/487 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DLG1 | c.1226A>G p.Y409C | Missense Mutation (SNP) | VAF 16/337 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.074); called by muse, mutect2
- EED | c.748A>T p.K250* | Nonsense Mutation (SNP) | VAF 91/91 reads (100%) | called by muse, mutect2, varscan2
- FAM131B | c.829A>G p.K277E | Missense Mutation (SNP) | VAF 44/992 reads (4%) | SIFT tolerated (0.89); PolyPhen benign (0.01); called by muse, mutect2
- FAM135B | c.3257A>T p.E1086V | Missense Mutation (SNP) | VAF 79/243 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- FAT2 | c.324C>A p.N108K | Missense Mutation (SNP) | VAF 43/513 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FBXO22 | c.794+3A>G | Splice Region (SNP) | VAF 164/377 reads (44%) | called by muse, mutect2, varscan2
- FCRL6 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 145/326 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLNA | c.4945+1G>T p.X1649_splice | Splice Site (SNP) | VAF 209/413 reads (51%) | called by muse, mutect2, varscan2
- FUT9 | c.273C>G p.C91W | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GON4L | c.1483A>G p.T495A | Missense Mutation (SNP) | VAF 95/294 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- GPR141 | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 32/714 reads (4%) | called by muse, mutect2
- GRIN1 | c.242A>G p.D81G | Missense Mutation (SNP) | VAF 176/370 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- GYPC | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 110/227 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- IQUB | c.349T>C p.S117P | Missense Mutation (SNP) | VAF 46/485 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2
- IZUMO1R | c.38C>T p.T13I | Missense Mutation (SNP) | VAF 130/131 reads (99%) | SIFT tolerated (0.41); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KIDINS220 | c.3353_3373delinsAC p.P1118Hfs*5 | Frame Shift Del (DEL) | VAF 133/352 reads (38%) | called by pindel, varscan2*
- KIF4A | c.783_786del p.N262Lfs*11 | Frame Shift Del (DEL) | VAF 106/257 reads (41%) | called by mutect2, pindel, varscan2
- LARGE2 | c.1882del p.R628Afs*121 | Frame Shift Del (DEL) | VAF 103/435 reads (24%) | called by mutect2, pindel, varscan2
- LRP2 | c.3943T>C p.W1315R | Missense Mutation (SNP) | VAF 160/490 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAN2B2 | c.1350G>T p.M450I | Missense Mutation (SNP) | VAF 174/242 reads (72%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- MARCOL | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 191/323 reads (59%) | called by muse, mutect2, varscan2
- MCM9 | c.2244G>A p.M748I | Missense Mutation (SNP) | VAF 187/329 reads (57%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MEX3C | c.986T>C p.V329A | Missense Mutation (SNP) | VAF 12/211 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); called by muse, mutect2
- MGAM | c.4349T>A p.L1450* | Nonsense Mutation (SNP) | VAF 72/284 reads (25%) | called by muse, mutect2, varscan2
- MICU3 | c.1325C>G p.A442G | Missense Mutation (SNP) | VAF 130/252 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MSH6 | c.1132A>G p.R378G | Missense Mutation (SNP) | VAF 155/321 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- MTREX | c.650C>A p.T217N | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- MUC6 | c.6338A>T p.H2113L | Missense Mutation (SNP) | VAF 82/323 reads (25%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MYH10 | c.929T>C p.L310P | Missense Mutation (SNP) | VAF 32/237 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYH7 | c.3565del p.A1189Pfs*25 | Frame Shift Del (DEL) | VAF 50/91 reads (55%) | called by mutect2, varscan2
- NCOR1 | c.2956_2963del p.E986Kfs*29 | Frame Shift Del (DEL) | VAF 127/296 reads (43%) | called by mutect2, pindel, varscan2
- NCR3LG1 | c.1189T>C p.S397P | Missense Mutation (SNP) | VAF 233/294 reads (79%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- NLRC5 | c.2176A>C p.I726L | Missense Mutation (SNP) | VAF 172/504 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.065); called by muse, mutect2
- OFD1 | c.2042A>G p.N681S | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT tolerated (0.85); PolyPhen benign (0.009); called by muse, mutect2
- OR14C36 | c.493C>G p.P165A | Missense Mutation (SNP) | VAF 112/370 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- OR1K1 | c.637C>A p.L213M | Missense Mutation (SNP) | VAF 30/676 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.771); called by muse, mutect2
- P3H3 | c.717_718insAA p.E240Kfs*81 | Frame Shift Ins (INS) | VAF 210/545 reads (39%) | called by mutect2, pindel, varscan2
- PIK3CA | c.1259_1264del p.C420_P421del | In Frame Del (DEL) | VAF 71/198 reads (36%) | called by mutect2, pindel, varscan2
- PSMC1 | c.449T>C p.V150A | Missense Mutation (SNP) | VAF 82/234 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RPGRIP1 | c.833del p.R278Hfs*15 | Frame Shift Del (DEL) | VAF 115/310 reads (37%) | called by mutect2, pindel, varscan2
- RPS2 | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 51/478 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.127); called by mutect2, varscan2
- RPS6 | c.50_54del p.E17Gfs*3 | Frame Shift Del (DEL) | VAF 97/254 reads (38%) | called by mutect2, pindel, varscan2
- S1PR4 | c.359T>C p.L120P | Missense Mutation (SNP) | VAF 318/481 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SEMG2 | c.1581_1582del p.G528Sfs*5 | Frame Shift Del (DEL) | VAF 181/443 reads (41%) | called by mutect2, pindel, varscan2
- SF3B2 | c.1883T>C p.V628A | Missense Mutation (SNP) | VAF 196/390 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SFI1 | c.1820T>C p.V607A (on ENST00000400288 / NM_001007467.3; = p.V576A on NM_014775.4) | Missense Mutation (SNP) | VAF 14/382 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.225); called by muse, mutect2
- SI | c.3931T>A p.F1311I | Missense Mutation (SNP) | VAF 117/285 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC2A11 | c.1030G>T p.G344W (on ENST00000345044 / NM_001024938.4; = p.G351W on NM_030807.5) | Missense Mutation (SNP) | VAF 106/458 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNRNP25 | c.339A>T p.R113= (on ENST00000383018; = p.R104= on NM_024571.4) | Splice Region (SNP) | VAF 98/333 reads (29%) | called by muse, mutect2, varscan2
- SRCAP | c.2621C>T p.A874V | Missense Mutation (SNP) | VAF 148/315 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- STX17 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 150/285 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- SUGCT | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 120/438 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- SYT4 | c.247A>C p.N83H | Missense Mutation (SNP) | VAF 153/164 reads (93%) | SIFT tolerated (0.15); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- TAT | c.821C>G p.S274C | Missense Mutation (SNP) | VAF 62/396 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENM1 | c.6076A>G p.I2026V | Missense Mutation (SNP) | VAF 52/431 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- THEM4 | c.76G>T p.G26* | Nonsense Mutation (SNP) | VAF 191/377 reads (51%) | called by mutect2, varscan2
- THRAP3 | c.1229A>G p.K410R | Missense Mutation (SNP) | VAF 188/404 reads (47%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TIMM44 | c.127G>T p.G43* | Nonsense Mutation (SNP) | VAF 21/261 reads (8%) | called by muse, mutect2
- TMPRSS11F | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 37/201 reads (18%) | called by muse, mutect2, varscan2
- TRHR | c.868T>C p.S290P | Missense Mutation (SNP) | VAF 128/421 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM40 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 72/387 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRIO | c.5857T>C p.S1953P | Missense Mutation (SNP) | VAF 116/346 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- UBAP1L | c.130dup p.S44Kfs*24 | Frame Shift Ins (INS) | VAF 195/509 reads (38%) | called by mutect2, pindel, varscan2
- VTN | c.631A>G p.T211A | Missense Mutation (SNP) | VAF 126/373 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- WWOX | c.540_548del p.M180_D183delinsI | In Frame Del (DEL) | VAF 82/235 reads (35%) | called by mutect2, pindel, varscan2
- XPO5 | c.3181T>C p.S1061P | Missense Mutation (SNP) | VAF 63/221 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- YEATS2 | c.288_291+6del p.X96_splice | Splice Site (DEL) | VAF 87/239 reads (36%) | called by mutect2, pindel, varscan2
- ZFHX2 | c.2815A>G p.T939A | Missense Mutation (SNP) | VAF 128/446 reads (29%) | SIFT tolerated (0.43); called by muse, mutect2, varscan2
- ZNF250 | c.717C>A p.S239R | Missense Mutation (SNP) | VAF 124/415 reads (30%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- ZNF770 | c.1099A>G p.R367G | Missense Mutation (SNP) | VAF 142/283 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHNAK2 | c.7116C>T p.S2372= | Silent (SNP) | VAF 264/481 reads (55%) | catalogued as rs370430674; called by muse, mutect2, varscan2
- ALAS2 | c.687C>T p.I229= | Silent (SNP) | VAF 34/744 reads (5%) | called by muse, mutect2
- ANKRD13B | c.1821C>T p.R607= | Silent (SNP) | VAF 283/591 reads (48%) | called by muse, mutect2, varscan2
- BTNL9 | c.276C>A p.L92= | Silent (SNP) | VAF 92/375 reads (25%) | called by muse, mutect2, varscan2
- CAMTA2 | c.1506T>C p.S502= | Silent (SNP) | VAF 165/394 reads (42%) | called by muse, mutect2
- CCDC18 | c.3849A>G p.V1283= (on ENST00000343253 / NM_001306076.1; = p.V1284= on NM_206886.4) | Silent (SNP) | VAF 12/121 reads (10%) | called by muse, mutect2, varscan2
- CCSER1 | c.1212G>A p.A404= | Silent (SNP) | VAF 127/165 reads (77%) | catalogued as rs765906575; called by muse, mutect2, varscan2
- CSMD1 | c.3054T>C p.T1018= (on ENST00000520002; = p.T1017= on NM_033225.6) | Silent (SNP) | VAF 209/440 reads (48%) | catalogued as COSV59333256; called by muse, mutect2, varscan2
- DNAH10 | c.4275G>A p.T1425= (on ENST00000409039; = p.T1364= on NM_207437.3) | Silent (SNP) | VAF 191/420 reads (45%) | catalogued as rs372606019; called by muse, mutect2, varscan2
- EMID1 | c.621C>A p.T207= | Silent (SNP) | VAF 108/298 reads (36%) | catalogued as COSV100469234; called by muse, varscan2
- FLRT1 | c.48C>G p.A16= | Silent (SNP) | VAF 20/549 reads (4%) | called by muse, mutect2
- FREM2 | c.2382C>T p.G794= | Silent (SNP) | VAF 207/207 reads (100%) | catalogued as rs779270736; called by muse, mutect2, varscan2
- GPC5 | c.1344C>A p.V448= | Silent (SNP) | VAF 138/284 reads (49%) | called by mutect2, varscan2
- H3Y1 | c.219C>T p.R73= | Silent (SNP) | VAF 116/327 reads (35%) | called by muse, mutect2, varscan2
- HROB | c.1602G>A p.T534= | Silent (SNP) | VAF 106/226 reads (47%) | catalogued as rs759193752; called by muse, mutect2, varscan2
- KDM1B | c.483A>G p.P161= | Silent (SNP) | VAF 133/335 reads (40%) | called by muse, mutect2, varscan2
- MAGI2 | c.378G>A p.Q126= | Silent (SNP) | VAF 187/587 reads (32%) | catalogued as COSV100835220; called by muse, mutect2, varscan2
- MGAM | c.1131G>A p.A377= | Silent (SNP) | VAF 170/550 reads (31%) | catalogued as rs1554461448, COSV101527453; called by muse, mutect2
- MUC12 | c.13683A>C p.S4561= (on ENST00000379442; = p.S4418= on NM_001164462.1) | Silent (SNP) | VAF 63/1854 reads (3%) | catalogued as rs1258310237; called by muse, mutect2
- MXI1 | c.105G>A p.P35= | Silent (SNP) | VAF 238/238 reads (100%) | catalogued as rs1391946430, COSV53292226; called by muse, mutect2, varscan2
- MYH14 | c.3876A>G p.R1292= | Silent (SNP) | VAF 28/311 reads (9%) | called by muse, mutect2
- NECAB1 | c.420G>T p.L140= | Silent (SNP) | VAF 170/355 reads (48%) | called by muse, mutect2, varscan2
- OR51F2 | c.475T>C p.L159= | Silent (SNP) | VAF 236/302 reads (78%) | called by muse, mutect2, varscan2
- PTPRQ | c.5991T>C p.D1997= (on ENST00000616559; = p.D1955= on NM_001145026.2) | Silent (SNP) | VAF 141/295 reads (48%) | called by muse, mutect2, varscan2
- RPA1 | c.159A>G p.L53= | Silent (SNP) | VAF 122/214 reads (57%) | catalogued as rs139235121; called by muse, mutect2, varscan2
- RPL23 | c.141A>G p.G47= | Silent (SNP) | VAF 44/383 reads (11%) | called by muse, mutect2, varscan2
- SEC63 | c.858A>G p.L286= | Silent (SNP) | VAF 133/253 reads (53%) | called by muse, mutect2, varscan2
- SELL | c.468C>T p.N156= (on ENST00000650983; = p.N143= on NM_000655.5) | Silent (SNP) | VAF 146/317 reads (46%) | catalogued as rs777328659, COSV99357396, COSV99357923; called by muse, mutect2, varscan2
- SERPINA11 | c.135C>T p.P45= | Silent (SNP) | VAF 244/472 reads (52%) | catalogued as rs370347481; called by muse, mutect2, varscan2
- SERPINE1 | c.741G>T p.L247= | Silent (SNP) | VAF 147/563 reads (26%) | called by muse, mutect2, varscan2
- SP8 | c.825C>G p.A275= (on ENST00000361443 / NM_198956.4; = p.A293= on NM_182700.6) | Silent (SNP) | VAF 260/1088 reads (24%) | called by muse, mutect2, varscan2
- SUCO | c.3153T>C p.N1051= | Silent (SNP) | VAF 84/261 reads (32%) | called by muse, mutect2, varscan2
- TDRD9 | c.207G>A p.A69= | Silent (SNP) | VAF 140/330 reads (42%) | called by muse, mutect2, varscan2
- TRAT1 | c.108G>A p.K36= | Silent (SNP) | VAF 156/323 reads (48%) | catalogued as COSV99849386; called by muse, mutect2, varscan2
- TRAV8-6 | c.240C>T p.N80= | Silent (SNP) | VAF 224/442 reads (51%) | called by muse, mutect2
- TRPM6 | c.309A>G p.G103= | Silent (SNP) | VAF 124/275 reads (45%) | called by muse, mutect2, varscan2
- XAB2 | c.852G>A p.R284= | Silent (SNP) | VAF 128/373 reads (34%) | called by muse, mutect2, varscan2
- ZNF282 | c.438C>T p.H146= | Silent (SNP) | VAF 199/612 reads (33%) | called by muse, mutect2, varscan2
- ANKRD20A8P | n.1198C>A | RNA (SNP) | VAF 23/546 reads (4%) | called by muse, mutect2
- INTS11 | c.429+311T>C | Intron (SNP) | VAF 260/525 reads (50%) | catalogued as rs758672427; called by muse, mutect2, varscan2
- LACTBL1 | c.389+13G>T | Intron (SNP) | VAF 277/561 reads (49%) | called by muse, mutect2, varscan2
- SALL2 | c.*575_*576del | 3'UTR (DEL) | VAF 197/490 reads (40%) | called by pindel, varscan2
- SPTLC1 | c.427+455A>G | Intron (SNP) | VAF 208/376 reads (55%) | called by muse, mutect2, varscan2
- ST7 | c.151+66926A>G | Intron (SNP) | VAF 56/651 reads (9%) | catalogued as rs1487578462; called by muse, mutect2
- TMEM161B | chr5:88190132 C>G | 3'Flank (SNP) | VAF 45/264 reads (17%) | called by muse, mutect2, varscan2
